Gene-level copy-number profile of specimen HCM-SANG-0526-C15-85A-01D-A80T-32 from HCMI case HCM-SANG-0526-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G3.
Specimen HCM-SANG-0526-C15-85A-01D-A80T-32: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 5d7f94a3-b0e9-4c24-a45e-3b7ebc3c494d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0526-C15-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,733 have no estimate.
https://portal.gdc.cancer.gov/files/93d953c5-0673-4269-8066-0bab32d583fe

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 2,498; copy number 2: 20,145; copy number 3: 22,393; copy number 4: 11,708; copy number 5: 1,157; copy number 6: 129; copy number 7: 497; copy number 8: 146; copy number 9: 7; copy number 10: 200; copy number 11: 9.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:22,046,758–22,046,901, 1 gene (within-gene range 0–2): AL354709.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 859 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:37,032–29,567,293, 497 genes, copy number 7 (within-gene range 7–8) (broad region; genes not listed).
- chr12:166,856–5,026,012, 118 genes, copy number 8 (within-gene range 5–10) (broad region; genes not listed).
- chr13:21,492,691–23,676,104, 33 genes, copy number 10–11: MICU2, FNTAP2, RNU6-59P, RPS7P10, FGF9, RN7SL766P, LINC00424, LINC00540, NME1P1, MTND3P1, FTH1P7, DDX39AP1, SNORD36, RPL7AP73, IPMKP1, RFESDP1, LINC00621, BASP1P1, NUS1P2, AL157931.1, HMGA1P6, RNY3P4, LINC00362, SGCG, RNU6-58P, TATDN2P3, SDAD1P4, SACS, RPLP1P13, SACS-AS1, LINC00327, LINC00352, TNFRSF19.
- chr13:28,659,104–34,928,076, 96 genes, copy number 10 (broad region; genes not listed).
- chr13:37,103,259–42,323,261, 87 genes, copy number 9–10 (broad region; genes not listed).
- chr16:24,845,841–26,358,355, 28 genes, copy number 8: SLC5A11, ARHGAP17, AC133552.1, AC133552.2, LINC02175, SCML2P2, AC133552.4, LCMT1-AS1, AC133552.3, AC133552.5, LCMT1, LCMT1-AS2, RN7SL557P, AQP8, ZKSCAN2, AC008741.1, ZKSCAN2-DT, LINC02191, CYCSP39, HS3ST4, AC093516.1, AC093524.1, MIR548W, RNA5SP405, HMGN2P3, HSPE1P16, AC009158.1, AC130464.1.

Autosomal genes at a single copy (total copy number 1): 2,498. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
